Surgical pathology report (de-identified scan), TCGA case TCGA-EM-A4FV, project TCGA-THCA (Thyroid Carcinoma), tissue source site University Health Network, specimen TCGA-EM-A4FV-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology Consultation Report

Patient Name: [REDACTED]
MRN: [REDACTED]
DOB: [REDACTED]
Gender: F
Ordering MD: [REDACTED]
Copy To: [REDACTED]

Service: [REDACTED]
Visit #: [REDACTED]
Location: [REDACTED]
Facility: [REDACTED]

Accession #: [REDACTED]
Collected: [REDACTED]
Received: [REDACTED]
Reported: [REDACTED]

Specimen(s) Received

1. Parathyroid: Left lower parathyroid QS
2. Thyroid: Right paratracheal node
3. Thyroid: Total thyroid, stitch marks upper pole left lobe (fresh for tumour banking)

Diagnosis

1. No pathological diagnosis: Parathyroid (left lower) biopsy
2. No pathological diagnosis: Lymph nodes, 2 (right paratracheal) biopsy
3. Papillary carcinoma, follicular variant, 1.3 cm: Thyroid
No pathological diagnosis: Lymph nodes, 3
- total thyroidectomy specimen

ICD-0-3

CQCF: carcinoma, papillary, thyroid 0200/3
Path: carcinoma, papillary, follicular variant
8340/3

Synoptic Data

Procedure:	Total thyroidectomy
Received:	Fresh
Specimen Integrity:	Intact
Specimen Size:	Right lobe: 3.8 cm 2.3 cm 0.7 cm Left lobe: 3.5 cm 2.6 cm 1.1 cm Isthmus +/- pyramidal lobe: 1.1 cm 0.9 cm 0.1 cm
Specimen Weight:	7.8 g
Tumor Focality:	Unifocal
----- DOMINANT TUMOR -----	
Tumor Laterality:	Left lobe
Tumor Size:	Greatest dimension: 1.3cm Additional dimension: 1.2 cm Additional dimension: 1.1 cm

Site: thyroid, nos c73.9

pw
10/2/12

[page 2 of 2]
Surgical Pathology Consultation Report

Histologic Type: Papillary carcinoma, follicular variant (4V = 95% per TSS)
Follicular architecture
Classical cytomorphology
Histologic Grade: Not applicable
Margins: Margins uninvolved by carcinoma
Tumor Capsule: Totally encapsulated
Tumor Capsular Invasion: Present, extent widely invasive
Lymph-Vascular Invasion: Not identified
Perineural Invasion: Not identified
Extrathyroidal Extension: Not identified
TNM Descriptors: Not applicable
Primary Tumor (pT): pT1b: Tumor more than 1 cm but not more than 2 cm in greatest dimension, limited to the thyroid
Regional Lymph Nodes (pN): pN0: No regional lymph node metastasis
Number of regional lymph nodes examined: 5
Number of regional lymph nodes involved: 0
Distant Metastasis (pM): Not applicable
Additional Pathologic Findings: None Identified

*Pathologic Staging is based on AJCC/UICC TNM, 7th Edition

Electronically verified by:

Gross Description

1. The specimen labeled with the patient's name and as "LT lower parathyroid QS" contains a piece of tissue that measures 0.6 x 0.3 x 0.2 cm. It is frozen for intraoperative consultation.

1A frozen tissue resubmitted

2. The specimen labeled with the patient's name and as "Right paratracheal node" contains a piece of fibroadipose tissue measuring 1.4 x 0.9 x 0.2 cm. There are 2 lymph nodes measuring 0.1 and 0.2 cm.

2A submitted in

3. The specimen labeled with the patient's name and as "Total thyroid, stitch marks upper pole left lobe (fresh)" contains a thyroid gland that is oriented with a suture and weighs 7.8 g. The right lobe measures 3.8 cm SI x 2.3 cm ML x 0.7 cm AP, the left lobe measures 3.5 cm SI x 2.6 cm ML x 1.1 cm AP and the isthmus measures 1.1 cm SI x 0.9 cm ML x 0.1 cm AP. The external surfaces have fibrous adhesions. No parathyroid glands and/or lymph nodes are identified grossly. The external surface is painted with silver nitrate. The left lower lobe contains a delineated nodule that measures 1.3 cm SI x 1.2 cm ML x 1.1 cm AP. The remainder of the thyroid tissue is grossly unremarkable. Sections of the nodule and normal tissue are stored frozen. The remainder of the specimen is submitted as follows:

3A-E right lobe, superior to inferior

3F isthmus

3G-K left lobe, superior to inferior (nodule in 3J and 3K)

Quick Section Diagnosis

1. Left lower parathyroid for QS: Parathyroid tissue present

Result reported at

Hi-PPA Discrepancy		
Case is (check)		

Source: NCI Genomic Data Commons file 431fe5cb-a7a9-434e-a9a3-cc4dbcd54ed1 (TCGA-EM-A4FV.3065BB69-9440-4CB2-B0E3-186619499DF0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).